Somatic mutation profile of tumor specimen MP2PRT-PAUUIY-TMP1-A (aliquot MP2PRT-PAUUIY-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUUIY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (883 days).
Specimen MP2PRT-PAUUIY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69f1d220-0caa-4694-818c-4c8f33219a98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUUIY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUUIY-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca930333-84a6-4aaa-ba78-da51f5052ef3

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP3 | c.694G>A p.A232T (on ENST00000622464; = p.A268T on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV58994869; called by muse, mutect2, varscan2
- HSPG2 | c.12740G>T p.G4247V | Missense Mutation (SNP) | VAF 32/464 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60829040; called by muse, mutect2
- IGSF9B | c.3104G>A p.R1035H | Missense Mutation (SNP) | VAF 48/522 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.98); catalogued as rs372950944; called by muse, mutect2
- ITGB5 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 141/408 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1456364848, COSV56147338; called by muse, mutect2, varscan2
- LRRC55 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 109/291 reads (37%) | catalogued as rs1455490937; called by muse, mutect2, varscan2
- POLR1A | c.4810G>A p.D1604N | Missense Mutation (SNP) | VAF 124/316 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.916); catalogued as rs748890003; called by muse, varscan2
- RASGRF1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 126/328 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs371901610; called by muse, mutect2, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 56/559 reads (10%) | called by mutect2, pindel
- PTPRN | c.783C>T p.Y261= | Silent (SNP) | VAF 144/364 reads (40%) | catalogued as rs549588185, COSV55352002; called by muse, mutect2, varscan2
